Somatic mutation profile of tumor specimen BA2676D (aliquot aq-BA2676D) from BEATAML1.0 case 2008, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Refractory anemia with excess blasts; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.9 years (17,858 days).
Specimen BA2676D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4be8229d-c6bb-48c3-a95e-82addd1c1b82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2351D (Solid Tissue Normal), aliquot aq-BA2351D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1ca6420-5317-4836-9474-1e26eabd2601

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 43/79 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 17/42 reads (40%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, pindel, varscan2
- FBLN2 | c.2949C>G p.I983M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371133206; called by muse, mutect2, varscan2
- KIF1B | c.1671G>C p.R557S (on ENST00000377086 / NM_001365952.1; = p.R511S on NM_015074.3) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV99824632; called by muse, varscan2
- PRKACB | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142392871; called by muse, mutect2, varscan2
- TET2 | c.1364C>G p.P455R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV54396956; called by muse, mutect2, varscan2
- UBXN6 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs759550086, COSV56680095; called by muse, mutect2, varscan2
- ACTL7A | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- BCAR1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAPRIN2 | c.352dup p.Y118Lfs*2 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- PCDHB4 | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SNCG | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- USP34 | c.2330G>A p.S777N | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZAR1L | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PUS7 | c.549G>A p.Q183= | Silent (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1302C>T p.F434= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs757057701; called by muse, mutect2, varscan2
- SLC9A3 | c.1692C>T p.T564= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs770238478, COSV53804033; called by muse, mutect2, varscan2
- USP31 | c.153G>T p.S51= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- AC008619.1 | chr5:170483126 C>A | 3'Flank (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- GCKR | c.644+543C>T | Intron (SNP) | VAF 33/86 reads (38%) | catalogued as rs770681438; called by muse, mutect2, varscan2
